Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A6F2, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A6F2-01A (Primary Tumor).

Department of Cancer Pathology

C64F ICD-O-3
Adenocarcinoma, intestinal
type, tubular (8144/3)
Code to highest 8211/3
path Adenocarcinoma, w/ mixed satelites
(tubular + mucinous) 8255/3
Site C64F Stomach NOS
path 02/25/13

Patient: XXX

Age:

Gender: M

7/0/25/13

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) ca ventriculi

Date of admission:

Material:

1) Material: stomach, stomach with the tumour. Method of collection: Total organ resection

Histopathological diagnosis

Examination performed on:

Stomach mucinous adenocarcinoma.
(G3, pT2, pNO). (8490/3 T-63000)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

The specimen containing the stomach, after being incised along the greater curvature sized 15.3 x 10.8cm with the omentum sized 26.0 x 11.0cm. On the front wall, tumour sized 4.2 x 2.6 x 0.9cm. Distance from the proximal end: 4.6cm, from distal end: 7.8cm.

Microscopic description:

Gastric adenocarcinoma, tubular, partly mucinous (G3, mixed type) – the whole thickness of the stomach wall invaded (pT2).
Incision lines, omentum, vessels and lymph nodes (10) – free of neoplastic lesions.

Assistant:

Pathologist:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Per TSS, tubular is 90%

BLR

Distal Synchronous Prior Reported		
Case is (c) (4)		

Source: NCI Genomic Data Commons file 79a4fe8f-12dc-4af8-91a4-4503feae8511 (TCGA-D7-A6F2.60E461B5-221D-468F-90AA-045550148064.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).